Somatic mutation profile of tumor specimen TCGA-77-8146-01A (aliquot TCGA-77-8146-01A-11D-2244-08) from TCGA case TCGA-77-8146, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.6 years (26,533 days).
Specimen TCGA-77-8146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b6a11fd-11fe-4841-86b1-5cb9dbf71a9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8146-10A (Blood Derived Normal), aliquot TCGA-77-8146-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1d08f19-edb1-49cc-99f0-fa0865e96f26

The open-access MAF lists 169 somatic variants for this specimen: 120 protein-altering or splice-affecting, 44 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 44, Nonsense Mutation 5, Frame Shift Del 4, Intron 3, Splice Region 2, 3'UTR 1, Splice Site 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 47/84 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1555526268, CM971503, COSV52676850, COSV52715987, COSV52740951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.9260C>G p.S3087C | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV101446958, COSV71288299; called by muse, mutect2, varscan2
- ACLY | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100709694; called by muse, mutect2, varscan2
- ADAM7 | c.1795A>G p.T599A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99443954; called by muse, mutect2, varscan2
- ADGRV1 | c.8868T>G p.D2956E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101315974; called by muse, mutect2, varscan2
- AGTR1 | c.211G>C p.A71P | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100837043, COSV62560576; called by muse, mutect2
- AP3B1 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99670589, COSV99671381; called by muse, mutect2, varscan2
- APPL2 | c.1192G>T p.V398L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV99314788; called by muse, mutect2, varscan2
- ASIC4 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs761108415, COSV61732590; called by muse, mutect2
- ATG2B | c.5703A>G p.V1901= | Splice Region (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99952059; called by muse, mutect2, varscan2
- ATP2B4 | c.1215C>G p.Y405* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as COSV100397507; called by muse, mutect2, varscan2
- ATRIP | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1174135769, COSV100202755; called by muse, varscan2
- BACE2 | c.1383G>C p.Q461H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV100160804; called by muse, mutect2, varscan2
- C2orf16 | c.2152A>T p.T718S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.111); catalogued as COSV100820803; called by muse, mutect2, varscan2
- CADM2 | c.763C>A p.L255M (on ENST00000407528 / NM_001167674.2; = p.L257M on NM_153184.4) | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as COSV101055556, COSV67357833; called by muse, mutect2, varscan2
- CNTNAP4 | c.1679A>G p.H560R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100271455; called by muse, mutect2, varscan2
- COL12A1 | c.3610G>T p.V1204L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100485995; called by muse, mutect2, varscan2
- COL5A3 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs918725322, COSV99318915; called by muse, mutect2, varscan2
- CPXCR1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.393); catalogued as COSV99342209; called by mutect2, varscan2
- CSMD1 | c.1150G>C p.G384R (on ENST00000520002; = p.G383R on NM_033225.6) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101221036; called by muse, mutect2, varscan2
- CSPP1 | c.1562G>T p.R521L (on ENST00000676605; = p.R480L on NM_024790.6) | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767353646, COSV99138564; called by muse, mutect2, varscan2
- CTNNA2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768529296, COSV63553496, COSV63606300; called by muse, mutect2
- CTSZ | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99413576; called by muse, mutect2, varscan2
- CUBN | c.5209G>T p.A1737S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV100912647; called by muse, mutect2, varscan2
- CUBN | c.3976G>T p.D1326Y | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100912683; called by muse, mutect2, varscan2
- CUBN | c.3040A>T p.T1014S | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV100912684; called by muse, mutect2, varscan2
- DDI1 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 33/110 reads (30%) | catalogued as COSV100159186, COSV56376942; called by muse, mutect2, varscan2
- DENND5A | c.2267A>G p.K756R | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV100064676; called by muse, mutect2, varscan2
- DPP4 | c.2138T>C p.F713S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100858870; called by muse, mutect2, varscan2
- DPY19L3 | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100639191; called by muse, mutect2, varscan2
- EPHA6 | c.2242G>A p.G748R (on ENST00000389672 / NM_001080448.3; = p.G140R on NM_173655.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101062716; called by muse, mutect2, varscan2
- ERICH1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 130/314 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.883); catalogued as COSV100032506; called by muse, mutect2, varscan2
- FAM217A | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as COSV99212727; called by muse, mutect2, varscan2
- FBN1 | c.6514G>C p.V2172L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.339); catalogued as rs1243025749, COSV100355075; called by muse, mutect2, varscan2
- FCGR2C | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100912803; called by muse, mutect2, varscan2
- FFAR2 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99876063; called by muse, mutect2, varscan2
- FGF12 | c.718C>G p.Q240E (on ENST00000454309 / NM_021032.5; = p.Q178E on NM_004113.6) | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV99281178; called by muse, mutect2, varscan2
- FRMD6 | c.123G>C p.L41F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100655775; called by muse, mutect2, varscan2
- GABRG1 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV99778050; called by muse, mutect2, varscan2
- GALNT18 | c.1034G>C p.G345A | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99924618; called by muse, mutect2, varscan2
- GPD1L | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99245710; called by muse, varscan2
- HIPK3 | c.642C>G p.C214W | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100305787; called by muse, mutect2, varscan2
- HSPA14 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101000669; called by muse, mutect2, varscan2
- IQGAP1 | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV99185003; called by muse, mutect2, varscan2
- KCNH1 | c.2557G>A p.V853M (on ENST00000271751 / NM_172362.3; = p.V826M on NM_002238.4) | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.146); catalogued as COSV99659262; called by muse, mutect2, varscan2
- KEAP1 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260479, COSV50262144; called by muse, mutect2
- KIZ | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99851803; called by muse, mutect2, varscan2
- KRT83 | c.162C>A p.S54R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs750577277, COSV53342419; called by muse, mutect2, varscan2
- KRTAP10-10 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs191143712, COSV100553576; called by muse, mutect2, varscan2
- LRP1B | c.12052T>A p.C4018S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.214); catalogued as COSV101257030; called by muse, mutect2, varscan2
- LRRC55 | c.50C>A p.A17E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV101546743; called by muse, mutect2, varscan2
- MAP3K4 | c.4396+1G>C p.X1466_splice | Splice Site (SNP) | VAF 15/100 reads (15%) | catalogued as COSV100815369; called by muse, mutect2, varscan2
- MBD1 | c.909G>A p.P303= | Splice Region (SNP) | VAF 16/74 reads (22%) | catalogued as rs759943579, COSV99496385; called by muse, mutect2, varscan2
- MCTP1 | c.2098A>T p.S700C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100387193; called by muse, mutect2, varscan2
- MFSD1 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV99963806, COSV99964045; called by muse, mutect2, varscan2
- MYBPC3 | c.2806A>G p.T936A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV57023859, COSV99920378; called by muse, mutect2, varscan2
- MYH11 | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100258968; called by muse, mutect2, varscan2
- MYH2 | c.3827T>C p.I1276T | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV99820138; called by muse, mutect2, varscan2
- MYOZ2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100201695; called by muse, mutect2, varscan2
- NAA11 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99727358; called by muse, mutect2, varscan2
- NCR2 | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100897225; called by muse, mutect2, varscan2
- NEU2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs61750784, COSV52091841; called by muse, mutect2, varscan2
- NLGN4Y | c.385A>T p.T129S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV99946067; called by muse, mutect2, varscan2
- OR10K1 | c.585T>A p.S195R | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV99193558; called by muse, mutect2, varscan2
- OR10S1 | c.488G>T p.W163L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV101602442; called by muse, mutect2, varscan2
- OR1S2 | c.516C>A p.H172Q | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100224206; called by muse, mutect2, varscan2
- OR2A42 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV101195829; called by muse, mutect2, varscan2
- OR2D3 | c.943G>C p.G315R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV99549606; called by muse, mutect2, varscan2
- OR52N4 | c.107T>C p.M36T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs772340611, COSV100421677; called by muse, mutect2, varscan2
- OSBP2 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1326464889, COSV100213140; called by muse, mutect2, varscan2
- OSBPL6 | c.2147T>C p.M716T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748592141, COSV99507459; called by mutect2, varscan2
- PCARE | c.3476C>A p.P1159Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100527442; called by muse, mutect2, varscan2
- PCDHB3 | c.2386A>T p.S796C | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV50631000; called by muse, mutect2, varscan2
- PDIA3 | c.616T>C p.F206L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV100295087; called by muse, mutect2, varscan2
- PIP4P2 | c.600G>T p.M200I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53439840, COSV99575343; called by muse, mutect2, varscan2
- PNLIPRP3 | c.574C>G p.P192A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100982323, COSV100982482; called by muse, mutect2, varscan2
- POTEH | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 67/621 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs747485524, COSV58881978; called by muse, varscan2
- PPIL6 | c.866T>G p.L289* | Nonsense Mutation (SNP) | VAF 26/137 reads (19%) | catalogued as COSV101446737; called by muse, mutect2, varscan2
- PPM1B | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.037); catalogued as COSV99175785; called by muse, mutect2, varscan2
- PROKR2 | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.336); catalogued as CM065399, COSV99450247; called by muse, mutect2, varscan2
- RASA1 | c.3017C>G p.S1006* | Nonsense Mutation (SNP) | VAF 55/127 reads (43%) | catalogued as COSV56925103, COSV99169814; called by muse, mutect2, varscan2
- RPTOR | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV100156226; called by muse, mutect2, varscan2
- S1PR1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541554; called by muse, varscan2
- S1PR1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541556, COSV59513740; called by muse, varscan2
- SCARF1 | c.1728C>G p.I576M | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761464039, COSV99557045, COSV99557049; called by muse, mutect2, varscan2
- SCN1A | c.2303C>A p.P768Q (on ENST00000303395 / NM_001202435.3; = p.P757Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as CM099623, COSV100320438; called by muse, mutect2, varscan2
- SCUBE2 | c.2236G>A p.G746S (on ENST00000649792 / NM_001367977.2; = p.G689S on NM_020974.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100496660; called by muse, mutect2, varscan2
- SEPTIN14 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as COSV101193329; called by muse, mutect2, varscan2
- SF3B3 | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100091753; called by muse, mutect2, varscan2
- SGCZ | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 173/452 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV101169706; called by muse, mutect2, varscan2
- SH3RF1 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99498711, COSV99499031; called by muse, mutect2, varscan2
- SIK3 | c.3575G>T p.G1192V (on ENST00000445177 / NM_001366686.2; = p.G1150V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52609178, COSV99408012; called by muse, mutect2, varscan2
- SLC17A5 | c.755C>A p.P252Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100867071; called by muse, mutect2
- SLC17A7 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV55547414, COSV99676840; called by muse, mutect2, varscan2
- SLC18A2 | c.1171G>C p.V391L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100041664; called by muse, mutect2, varscan2
- SLIT2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV56602146, COSV99883849; called by muse, mutect2, varscan2
- SPAG6 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100510263; called by muse, mutect2
- SRRT | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs138829624; called by muse, mutect2, varscan2
- STRN4 | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV99623634; called by muse, mutect2, varscan2
- SUGCT | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1209606888, COSV100001845; called by muse, mutect2, varscan2
- SUPT5H | c.2383G>T p.D795Y | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100782077; called by muse, mutect2, varscan2
- TAF7 | c.723A>T p.E241D | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100514983; called by muse, mutect2, varscan2
- TESC | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs756764036, COSV100069366; called by muse, mutect2, varscan2
- THADA | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100368651; called by muse, mutect2, varscan2
- TNIK | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as rs373165373; called by muse, varscan2
- TNK2 | c.2839G>T p.G947C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100361331; called by muse, mutect2, varscan2
- TRAPPC12 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100160515; called by muse, mutect2, varscan2
- TRPC6 | c.2615T>G p.I872R | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100723619; called by muse, mutect2, varscan2
- TTC37 | c.3497C>T p.S1166L | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100706634, COSV62457003; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3100C>T p.H1034Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1486120495, COSV99511895; called by muse, mutect2, varscan2
- USH2A | c.10687T>C p.Y3563H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs756541958, COSV100234727; called by muse, mutect2, varscan2
- ZCCHC2 | c.1591A>G p.M531V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs752551391, COSV99502428; called by muse, mutect2, varscan2
- ZNF263 | c.1825G>C p.G609R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV99526908; called by muse, mutect2, varscan2
- ZNF347 | c.212G>C p.S71T | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100498297; called by muse, mutect2, varscan2
- KIR2DL4 | c.823+1del | Frame Shift Del (DEL) | VAF 73/329 reads (22%) | called by mutect2, pindel, varscan2
- MED23 | c.977del p.T326Kfs*35 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | called by mutect2, pindel, varscan2
- NMT2 | c.1067_1088del p.N356Ifs*5 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, pindel
- OR5L1 | c.284del p.L95Qfs*23 | Frame Shift Del (DEL) | VAF 52/210 reads (25%) | called by mutect2, pindel, varscan2
- ZNF277 | c.1048dup p.I350Nfs*31 | Frame Shift Ins (INS) | VAF 32/218 reads (15%) | called by pindel, varscan2
- ATR | c.7626G>T p.L2542= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100638240; called by muse, mutect2, varscan2
- CATSPERB | c.537G>T p.V179= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV99831278; called by muse, mutect2, varscan2
- CCT8L2 | c.399G>C p.R133= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100742762, COSV63462360; called by muse, mutect2, varscan2
- CD5L | c.525G>T p.V175= | Silent (SNP) | VAF 42/175 reads (24%) | catalogued as COSV100941051; called by muse, mutect2, varscan2
- DCC | c.3795C>T p.L1265= | Silent (SNP) | VAF 47/213 reads (22%) | catalogued as COSV101472988; called by muse, mutect2, varscan2
- DHX37 | c.726C>T p.S242= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV58138456; called by muse, mutect2, varscan2
- DIP2C | c.3048G>T p.V1016= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV99791697; called by muse, mutect2, varscan2
- EVI2B | c.48C>T p.N16= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as rs200921973, COSV100445490; called by muse, mutect2, varscan2
- FOXF1 | c.1056G>T p.A352= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV52287226, COSV52288039; called by muse, mutect2, varscan2
- FOXP1 | c.1539G>T p.V513= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100561695; called by muse, mutect2, varscan2
- GHSR | c.549G>C p.G183= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV99576938; called by muse, mutect2, varscan2
- GLI3 | c.3438C>T p.L1146= | Silent (SNP) | VAF 36/181 reads (20%) | catalogued as rs760545738, COSV67894816; called by muse, mutect2, varscan2
- HAS1 | c.1170C>T p.N390= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs755573585, COSV99708400; called by muse, mutect2, varscan2
- HIRA | c.18G>T p.P6= | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as COSV99600351; called by muse, mutect2, varscan2
- INTS2 | c.3375G>T p.L1125= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as COSV99248142; called by muse, mutect2, varscan2
- KATNAL2 | c.321G>A p.G107= (on ENST00000356157 / NM_001353899.1; = p.G35= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/277 reads (10%) | catalogued as COSV55292625; called by muse, mutect2, varscan2
- LRRTM1 | c.1128G>T p.S376= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99702556; called by muse, mutect2, varscan2
- MCM7 | c.1761G>A p.E587= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs761402052, COSV100384911; called by muse, mutect2, varscan2
- MICAL3 | c.2292C>T p.C764= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99261571; called by muse, mutect2, varscan2
- MUC5AC | c.15411G>A p.P5137= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs543190470, COSV64371223; called by muse, mutect2, varscan2
- MYH14 | c.3411G>A p.L1137= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1223412090, COSV99222716; called by muse, mutect2, varscan2
- MYH2 | c.3828C>T p.I1276= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99820137; called by muse, mutect2, varscan2
- NUMB | c.675C>T p.V225= (on ENST00000355058; = p.V214= on NM_003744.5) | Silent (SNP) | VAF 27/206 reads (13%) | catalogued as rs1369772648, COSV100679678; called by muse, mutect2, varscan2
- NUP153 | c.1644A>T p.T548= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100020301, COSV50460365; called by muse, mutect2, varscan2
- OR8J1 | c.552G>T p.L184= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV57319075; called by muse, mutect2, varscan2
- PCDHGA12 | c.897G>T p.G299= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as COSV52749968; called by muse, mutect2, varscan2
- PIAS2 | c.1797C>T p.S599= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV101286477; called by muse, mutect2, varscan2
- PKD1 | c.2766C>T p.L922= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs777269703, COSV99236955, COSV99238142; called by muse, mutect2, varscan2
- PPP1R3A | c.2049A>G p.E683= | Silent (SNP) | VAF 50/298 reads (17%) | catalogued as COSV99492946; called by muse, mutect2, varscan2
- PRAMEF17 | c.363C>T p.A121= | Silent (SNP) | VAF 92/201 reads (46%) | catalogued as COSV101068683; called by muse, mutect2, varscan2
- PRKN | c.1071C>A p.G357= | Silent (SNP) | VAF 73/240 reads (30%) | catalogued as COSV58209644; called by muse, mutect2, varscan2
- PRPF6 | c.1959C>T p.S653= | Silent (SNP) | VAF 41/311 reads (13%) | catalogued as rs757720133; called by muse, mutect2, varscan2
- PTPRU | c.3561C>T p.T1187= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV100112720; called by muse, mutect2, varscan2
- SCN1A | c.1101C>A p.T367= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100320439; called by muse, mutect2, varscan2
- SERPINA4 | c.519C>T p.Y173= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs764068417, COSV54069007; called by muse, mutect2, varscan2
- SLC7A2 | c.345T>A p.T115= (on ENST00000494857 / NM_001370338.1; = p.T155= on NM_003046.6) | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99134948; called by muse, mutect2, varscan2
- STRA6 | c.1752C>T p.F584= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV99997328; called by muse, mutect2, varscan2
- SYNE3 | c.672G>A p.E224= | Silent (SNP) | VAF 67/396 reads (17%) | catalogued as rs1374266544, COSV100516004; called by muse, mutect2, varscan2
- TENM1 | c.726C>T p.V242= | Silent (SNP) | VAF 64/161 reads (40%) | catalogued as COSV100950046; called by muse, mutect2, varscan2
- TIGD3 | c.888G>A p.L296= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV99361662; called by muse, mutect2, varscan2
- TMEM184A | c.705C>G p.L235= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs745872708, COSV99868248; called by muse, mutect2, varscan2
- TREM2 | c.207G>A p.L69= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV100632604; called by muse, mutect2, varscan2
- TTC3 | c.3363T>C p.H1121= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs1305614197, COSV100695518; called by muse, mutect2, varscan2
- ZBTB25 | c.465T>C p.S155= | Silent (SNP) | VAF 33/199 reads (17%) | catalogued as COSV101170728; called by muse, mutect2, varscan2
- EPDR1 | c.-68C>G | 5'UTR (SNP) | VAF 11/40 reads (28%) | catalogued as rs752656316, COSV99554415; called by muse, mutect2, varscan2
- LIAS | c.299+1532A>G | Intron (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99787688; called by muse, mutect2
- MAGI1 | c.2417-3558A>T | Intron (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100441018; called by muse, mutect2, varscan2
- RYR2 | c.11145+1271C>G | Intron (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100770242; called by muse, mutect2, varscan2
- VNN3 | c.*660G>T | 3'UTR (SNP) | VAF 13/44 reads (30%) | catalogued as rs767337546, COSV99258302; called by muse, mutect2, varscan2
